Gene-level copy-number profile of tumor specimen TCGA-LN-A4A3-01A from TCGA case TCGA-LN-A4A3, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.1 years (22,313 days).
Specimen TCGA-LN-A4A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.326fd2b8-fd17-4582-9584-f76e5078b549.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34007932-0f4f-4c26-9799-2a9bde171894

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 251; copy number 1: 38,502; copy number 2: 14,508; copy number 3: 5,823; copy number 4: 131; copy number 5: 337; copy number 6: 15; copy number 7: 106; copy number 10: 12; copy number 12: 33; copy number 13: 93; copy number 19: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4A3-01A-11D-A25X-01): tumor purity 0.51, ploidy 1.68, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 229 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr11:6,863,057–6,892,599, 3 genes: OR10A2, OR10A4, OR2D2.
- chr11:73,951,026–75,206,549, 50 genes (within-gene range 0–1): DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P, AP001992.1, AP001992.2, SPCS2, RNU6-216P, NEU3, AP003175.1, OR2AT2P, NPM1P50, OR2AT4, AP001972.4, SLCO2B1, OR2AT1P.
- chr19:6,531,026–7,702,146, 56 genes: TNFSF9, AC010503.3, CLIC4P2, Y_RNA, CD70, RPL7P50, TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR, AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2.
- chr19:20,077,994–22,533,494, 113 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,558 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:124,080,023–124,726,325, 1 gene, copy number 4 (within-gene range 2–4): KALRN.
- chr3:124,374,332–198,222,513, 1,355 genes, copy number 3–4 (broad region; genes not listed).
- chr7:70,972–57,777,521, 1,070 genes, copy number 3–19 (broad region; genes not listed).
- chr7:85,421,122–110,592,204, 501 genes, copy number 4–10 (broad region; genes not listed).
- chr7:110,724,159–110,725,825, 1 gene, copy number 5: AC073326.1.
- chr8:13,629,644–15,238,431, 14 genes, copy number 3 (within-gene range 2–3): AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383.
- chr8:43,672,823–145,066,685, 1,536 genes, copy number 3 (broad region; genes not listed).
- chr11:68,870,664–73,931,114, 173 genes, copy number 4–13 (broad region; genes not listed).
- chr12:3,296,202–15,006,999, 441 genes, copy number 3 (broad region; genes not listed).
- chr12:15,112,363–15,155,283, 2 genes, copy number 3: RERG-IT1, RERG-AS1.
- chr14:51,304,108–51,599,952, 6 genes, copy number 3 (within-gene range 1–3): LINC00519, LINC00640, AL358332.1, LINC02310, SETP2, FRMD6-AS2.
- chr14:51,522,864–51,522,967, 1 gene, copy number 3: RNU6-1291P.
- chr16:78,014,683–78,066,761, 4 genes, copy number 3: AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr20:87,250–16,053,197, 291 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr20:15,552,157–64,313,132, 1,162 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
